Gene-level copy-number profile of tumor specimen C3N-01016-02 from CPTAC case C3N-01016, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 56.9 years (20,787 days).
Specimen C3N-01016-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 80ff8c9e-e366-40db-83c0-7d34d2d577b1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01016-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,861 have no estimate.
https://portal.gdc.cancer.gov/files/901f2efc-02b8-467c-af10-ca5eb87c93cc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 262; copy number 1: 1,060; copy number 2: 30,652; copy number 3: 19,252; copy number 4: 6,817; copy number 5: 236; copy number 6: 73; copy number 7: 94; copy number 8: 24; copy number 9: 40; copy number 10: 84; copy number 11: 73; copy number 16: 95.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 719 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:37,534,449–43,968,022, 208 genes, copy number 9–16 (broad region; genes not listed).
- chr1:143,419,625–145,859,836, 81 genes, copy number 6–7 (broad region; genes not listed).
- chr9:60,914,407–61,666,386, 17 genes, copy number 5–6: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1, AL935212.2.
- chr11:102,746,968–102,836,766, 1 gene, copy number 5 (within-gene range 2–5): WTAPP1.
- chr11:102,770,502–104,164,379, 26 genes, copy number 5 (within-gene range 2–5): MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3, AP001486.1, DCUN1D5, AP001486.2, DYNC2H1, AP002961.1, MTCO3P15, MTATP6P15, MTCO2P15, MTCO1P15, MTND2P26, MTND1P36, AP003461.1, AP002989.1, MIR4693, PDGFD, AP003043.1, DDI1.
- chr12:18,080,869–27,972,733, 163 genes, copy number 5 (broad region; genes not listed).
- chr14:18,333,726–18,712,643, 22 genes, copy number 7: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.5, CR383656.1, CR383656.12, CR383656.8, CR383656.11, CR383656.3, RPL22P20, CR383656.4, CR383656.2, NF1P10.
- chr14:31,334,312–45,569,069, 201 genes, copy number 5–10 (within-gene range 4–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,010. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
